Somatic mutation profile of tumor specimen TCGA-KM-8441-01A (aliquot TCGA-KM-8441-01A-11D-2310-10) from TCGA case TCGA-KM-8441, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 61.1 years (22,303 days).
Specimen TCGA-KM-8441-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0589178-2c8f-4904-b0b5-703e7310ff6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KM-8441-10A (Blood Derived Normal), aliquot TCGA-KM-8441-10A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4b46321-d662-47db-9152-25e5af5ffc3b

The open-access MAF lists 19 somatic variants for this specimen: 17 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Nonsense Mutation 2, Frame Shift Del 1, RNA 1, In Frame Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAG3 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as rs1285251667, COSV100958286; called by muse, mutect2
- GALNS | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754731091; called by muse, varscan2
- HRG | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 31/138 reads (22%) | catalogued as COSV51646967; called by muse, mutect2, varscan2
- ITGAX | c.3457G>A p.G1153R | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1181521884; called by muse, mutect2, varscan2
- MTOR | c.6050T>C p.I2017T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63878340, COSV63880423; called by muse, mutect2, varscan2
- MUC16 | c.40200C>A p.D13400E | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.976); catalogued as rs774506906; called by muse, mutect2, varscan2
- PAMR1 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as rs1168532648, COSV53511380; called by muse, mutect2, varscan2
- TKTL1 | c.1546G>A p.V516I | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs782032377; called by muse, varscan2
- C9orf43 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2
- ENPP6 | c.185A>T p.Y62F | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2
- EPHX1 | c.871T>C p.Y291H | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FAM160B2 | c.1138del p.Q380Sfs*11 | Frame Shift Del (DEL) | VAF 26/91 reads (29%) | called by mutect2, pindel, varscan2
- GALNS | c.278_283del p.I93_R94del | In Frame Del (DEL) | VAF 18/79 reads (23%) | called by pindel, varscan2
- MEST | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SCAPER | c.1759C>A p.L587I | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.236); called by muse, mutect2
- SCAPER | c.1758G>T p.L586F | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- STIL | c.3250C>T p.R1084* | Nonsense Mutation (SNP) | VAF 42/163 reads (26%) | called by muse, mutect2, varscan2
- SPATA20 | c.1881G>T p.G627= (on ENST00000356488 / NM_001258372.1; = p.G643= on NM_022827.4) | Silent (SNP) | VAF 29/94 reads (31%) | called by muse, mutect2, varscan2
- LINC00544 | n.927G>T | RNA (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
